Surgical pathology report (de-identified scan), TCGA case TCGA-CN-6019, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-6019-01A (Primary Tumor).

[page 1 of 5]
Pathology Report [REDACTED] **FINAL**

Report Type Pathology Report

Date of Event [REDACTED]

Sex [REDACTED]

Authored by [REDACTED]

Hosp/Group [REDACTED]

Record Status FINAL

FINAL DIAGNOSIS:

PART 1: LEFT FLOOR OF MOUTH MARGIN, BIOPSY

NO TUMOR SEEN.

PART 2: LEFT ORAL CAVITY, COMPOSITE RESECTION

A. INVASIVE SQUAMOUS CELL CARCINOMA, AT LEAST 3.5 CM, WITH HIGHLY INFILTRATIVE GROWTH PATTERN, KERATINIZING, MODERATELY DIFFERENTIATED, INVOLVING LEFT ORAL TONGUE, FLOOR OF MOUTH AND OROPHARYNX.

B. BONE IS FREE OF TUMOR.

C. PERINEURAL INVASION IS IDENTIFIED.

D. VASCULAR INVASION IS ABSENT.

E. CARCINOMA EXTENDS TO LEFT GINGIVAL, LEFT LATERAL AND MEDIAL DEEP SOFT TISSUE EDGES. SEE OTHER PARTS FOR ADDITIONAL MARGINS.

F. PATHOLOGIC STAGE pT4 N0.

PART 3: LEFT NECK, LEVELS 1 THROUGH 4, DISSECTION

SEVENTEEN BENIGN LYMPH NODES (0/17).

PART 4: LEFT FLOOR OF MOUTH, EXCISION

NO TUMOR SEEN.

PART 5: ADDITIONAL DEEP MARGIN, EXCISION

NO TUMOR SEEN.

PART 6: MYLOHYOID, EXCISION

NO TUMOR SEEN.

PART 7: ADDITIONAL LEFT GINGIVAL MARGIN, BIOPSY

NO TUMOR SEEN.

PART 8: RIGHT EXTERNAL JUGULAR NODES, EXCISION

A. ONE BENIGN LYMPH NODE (0/1).

B. MINUTE FRAGMENT OF PAROTID TISSUE.

PART 9: RIGHT NECK, LEVELS 1 THROUGH 4, DISSECTION

A. NINETEEN BENIGN LYMPH NODES (0/19).

B. SUBMANDIBULAR GLAND WITH NO SIGNIFICANT PATHOLOGIC CHANGE.

PART 10: RIGHT NECK, LEVEL 2B, DISSECTION

EIGHT BENIGN LYMPH NODES (0/8).

[REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is submitted unfixed in twelve parts.

Part 1 is identified as "left floor of mouth margin" and is labeled with the patients name and initials xx. Received are two delicate fragments of tan soft tissue 1.4 x 0.6 x 0.4 cm and 0.7 x 0.4 x 0.3 cm. Entire specimen is taken for intraoperative frozen section diagnostic evaluation and totally submitted labeled 1AFS.

[page 2 of 5]
Part 2 is identified as "composite resection, left oral cavity, blue stitch on facial artery" and is labeled with the patient's name and initials xx. Received is an oral composite resection 8.0 x 5.0 x 3.5 cm overall comprised of oral tongue, floor of mouth, base of tongue, oropharynx and a 2.5 x 1.5 x 0.6 cm portion of what appears to be mandibular bone. An ill-defined 3.5 x 2.5 x 1.0 cm densely firm solid pale tan-white focally nodular lesion is identified within the region of the floor of mouth abutting the medial adjacent margin. An overall gross photograph is taken. Representative tissue is procured for the clinical tissue bank (areas marked with red ink)

INK CODE:

Green - left medial deep resection margin

Yellow - bone resection margin

Blue - left lateral deep resection margin

Black - remaining resection margins

CASSETTE CODE:

2AFS - left lateral pharyngeal margin frozen section tissue

2BFS - left gingival mucosal margin frozen section tissue

2CFS - left lateral deep soft tissue margin frozen section tissue

2DFS - medial deep soft tissue margin frozen section tissue

2E through 2G - representative cross sections of mass region of deep margin

2H through 2I - representative cross sections region of oral pharynx

2J through 2L - representative cross sections region of oral tongue

2M - representative cross section of bone resection margin

Part 3 is identified as "left neck 1 through 4" and is labeled with the patient's name and initials xx. Received is an unoriented selective neck dissection approximating levels 1 through 4 comprised of uniform appearing soft yellow lobulated fibroadipose tissue. The specimen is divided into 4 equal portions. On dissection numerous mildly firm tan lymph nodes are identified ranging from 0.1 to 0.1 x 0.1 up to 1.8 x 1.0 x 0.5 cm.

CASSETTE CODE:

3A through 3D - possible lymph node tissue dissected from sequentially divided quarters

Part 4 is identified as "left floor of mouth" and is labeled with the patient's name and initials xx. Received is a 2.2 x 1.0 x 0.8 cm unoriented portion of mildly firm red-tan tissue. The entire specimen is submitted labeled 4A.

Part 5 is identified as "additional deep margin" and is labeled with the patient's name and initials xx. Received are two unoriented portions of slightly rounded soft red-tan tissue 3.0 x 2.0 x 1.3 cm and 2.5 x 1.0 x 1.0 cm.

CASSETTE CODE:

5A - serial cross sections of smaller portion totally submitted

5B through 5D - serial cross sections of larger portion totally submitted

Part 6 is identified as "mylohyoid" and is labeled with the patient's name and initials xx. Received is an unoriented roughly ovate portion of mildly firm uniform appearing red-tan muscle tissue 3.5 x 1.5 x 1.0 cm. The external surface is marked with black ink. Representative cross sections to the short axis are submitted in one cassette labeled 6A.

Part 7 is identified as "additional left gingival margin" and is labeled with the patient's name and initials xx. Received is a 1.5 and 0.6 x 0.3 cm portion of tan soft tissue. Additionally received is a 0.3 x 0.2 x 0.1 cm fragment of pale tan bone tissue. The soft tissue portion of the specimen is entirely taken for intraoperative frozen section diagnostic evaluation.

CASSETTE CODE:

7AFS - frozen section tissue totally submitted

7B - bone tissue fragment totally submitted following decalcification

[page 3 of 5]
Part 8 is identified as "right external jugular nodes" and is labeled with the patient's name and initials xx. Received is a 1.0 x 0.8 x 0.3 cm fragment of mildly firm red-tan tissue. The entire specimen is submitted labeled 8A.

Part 9 is identified as "right neck 1 through 4" and is labeled with the patient's name and initials xx. Received is a 4.0 x 3.0 x 1.5 cm intact submandibular gland with attached selective neck dissection comprised of soft yellow lobulated uniform appearing fibroadipose tissue 8.0 x 3.0 x 0.8 cm. The submandibular gland is normally lobulated soft and tan on external and cut surfaces. Multiple mildly firm tan lymph nodes are dissected from the fibroadipose tissue ranging from 0.1 x 0.1 x 0.1 cm up to 1.0 x 0.5 x 0.3 cm.

CASSETTE CODE:

9A - representative submandibular gland

9B - possible lymph node tissue dissected from level 1

9C - possible lymph node tissue dissected from level 2

9D - possible lymph node tissue dissected from level 3

9E - possible lymph node tissue dissected from level 4

Part 10 is identified as "right neck 2B" and is labeled with the patient's name and initials xx. Received is a 3.5 x 2.0 x 1.0 cm unoriented portion of soft uniform elongated pale tan yellow adipose tissue. On dissection no lymph node tissue is grossly identified. The specimen is entire submitted labeled 10A and 10B.

GROSSED BY: [REDACTED])

INTRAOPERATIVE CONSULTATION:

1AFS: LEFT FLOOR OF MOUTH MARGIN (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. BENIGN

C. NO TUMOR SEEN ([REDACTED]).

2AFS: LEFT LATERAL PHARYNGEAL MARGIN, SHAVE (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. BENIGN

C. NO TUMOR SEEN ([REDACTED]).

2BFS: LEFT GINGIVAL MUCOSAL MARGIN, SHAVE (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. MALIGNANT

C. SMALL FOCUS OF INVASIVE SQUAMOUS CELL CARCINOMA ([REDACTED]).

2CFS: LEFT LATERAL DEEP SOFT TISSUE MARGIN, PERPENDICULAR (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. MALIGNANT

C. SQUAMOUS CELL CARCINOMA PRESENT AT MARGIN ([REDACTED]).

2DFS: MEDIAL DEEP SOFT TISSUE MARGIN, PERPENDICULAR (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. MALIGNANT

C. SQUAMOUS CELL CARCINOMA PRESENT AT MARGIN ([REDACTED]).

7AFS: ADDITIONAL LEFT GINGIVAL MARGIN (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. BENIGN

C. NO TUMOR SEEN ([REDACTED]).

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

[page 4 of 5]
The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of [REDACTED] to a maximum of [REDACTED] hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE: Resection: composite oral cavity resection

TUMOR SITE: Oral Cavity

TUMOR SIZE: Greatest dimension: 3.5 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G2

PRIMARY TUMOR (pT): pT4a

REGIONAL LYMPH NODES (pN): pN0

Number of regional lymph nodes examined: 45

Number of regional lymph nodes involved: 0

DISTANT METASTASIS (pM): pMX

MARGINS: Cannot be assessed

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Absent

PERINEURAL INVASION: Present

Comment: T4 - involvement of extrinsic tongue muscles

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Oral cavity cancer

PROCEDURE: Neck dissection

SPECIFIC CLINICAL QUESTION: Not answered

OUTSIDE TISSUE DIAGNOSIS: Not answered

PRIOR MALIGNANCY: Not answered

CHEMO RADIATION: Not answered

ORGAN TRANSPLANT: Not answered

IMMUNOSUPPRESSION: Not answered

OTHER DISEASES: Not answered

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Left Floor of Mouth Margin

Taken: 2 [REDACTED]

Stain/cnt: Block

H&E x 1: AFS

Part 2: Composite Resection, Left Oral Cavity

Taken: [REDACTED]

Stain/cnt: Block

H&E x 1: E

H&E x 1: F

H&E x 1: G

H&E x 1: H

H&E x 1: I

H&E x 1: J

H&E x 1: K

[page 5 of 5]
H&E x 1 L

H&E x 1 M

H&E x 1 [REDACTED]

H&E x 1 [REDACTED]

H&E x 1 [REDACTED]

H&E x 1 [REDACTED]

Decal x 1 (none)

Part 3: Left Neck 1-4

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

Part 4: Left Floor of Mouth

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

Part 5: Additional Deep Margin

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

Part 6: Mylohyoid

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

Part 7: Additional Left Gingival Margin

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 B

H&E x 1 AFS

Decal x 1 (none)

Part 8: Right External Jugular Nodes

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

Part 9: Right Neck 1-4

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

Part 10: Right Neck 2B

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

[REDACTED]

Source: NCI Genomic Data Commons file f60d80f0-e4d3-4df4-a541-17ba0e6c9a5f (TCGA-CN-6019.6F28E868-5622-42E2-BA7A-80380E364EBB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).